Somatic mutation profile of tumor specimen TCGA-2Y-A9GW-01A (aliquot TCGA-2Y-A9GW-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.6 years (23,587 days).
Specimen TCGA-2Y-A9GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c32f94a9-9afb-45b9-9294-6204412a5684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GW-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GW-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d77f179d-073c-47ab-82de-5e02bb1f647f

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 59, Silent 23, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772971021, COSV100741787; called by muse, mutect2, varscan2
- ANGPTL7 | c.236T>C p.M79T | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs1222751408; called by muse, mutect2
- ASCL2 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs1476096121, COSV100489954; called by muse, mutect2
- ATM | c.7283G>C p.R2428T | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV99589695; called by muse, mutect2, varscan2
- BACE1 | c.908A>C p.E303A | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV100475057; called by muse, mutect2, varscan2
- CACNA1E | c.4070A>G p.N1357S | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100702737; called by muse, mutect2, varscan2
- CASP8AP2 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV52750536, COSV99386824; called by muse, mutect2, varscan2
- CCDC54 | c.617A>C p.D206A | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53760120; called by muse, mutect2, varscan2
- CCK | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533678433, COSV58184183; called by muse, mutect2, varscan2
- COG1 | c.2582T>G p.L861R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245317; called by muse, mutect2, varscan2
- COL6A6 | c.1987G>T p.V663L | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100650285; called by muse, mutect2, varscan2
- CPED1 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100120767; called by muse, mutect2, varscan2
- DAG1 | c.1011G>T p.R337S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100444940; called by muse, mutect2, varscan2
- DNAH10 | c.1213G>C p.V405L (on ENST00000409039; = p.V344L on NM_207437.3) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101292278, COSV101292442; called by muse, mutect2, varscan2
- DOCK4 | c.4159C>A p.P1387T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101447866; called by muse, mutect2, varscan2
- F5 | c.3929C>G p.T1310R | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.462); catalogued as rs879158814; called by muse, mutect2, varscan2
- FGD5 | c.2790C>A p.D930E | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99548128; called by muse, mutect2, varscan2
- FOXRED2 | c.528C>T p.S176= | Splice Region (SNP) | VAF 28/109 reads (26%) | catalogued as rs756611081, COSV53402034; called by muse, mutect2, varscan2
- FSHR | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV58617732; called by muse, mutect2, varscan2
- GIGYF1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV51942809, COSV99309416; called by muse, mutect2, varscan2
- HERC2 | c.8410G>T p.G2804C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs571204932, COSV99873922; called by muse, mutect2, varscan2
- ITIH1 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as COSV99835276; called by muse, mutect2, varscan2
- KIAA1109 | c.10433T>A p.L3478Q | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99163836; called by muse, mutect2, varscan2
- LRP1B | c.5712G>T p.M1904I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs932656739, COSV67182183; called by muse, mutect2, varscan2
- MARF1 | c.3430T>C p.S1144P | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100705933; called by muse, mutect2, varscan2
- MAST2 | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1490320007, COSV100788129; called by muse, mutect2, varscan2
- ME2 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs532005925, COSV100360784; called by muse, mutect2
- MST1 | c.1777A>G p.T593A | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99610795; called by muse, varscan2
- MTSS2 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV100116523; called by muse, mutect2, varscan2
- NCOA7 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV99997144; called by muse, mutect2, varscan2
- NRTN | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs748453602, COSV54607643; called by muse, mutect2, varscan2
- OR2T35 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100442276; called by muse, mutect2, varscan2
- OSBPL3 | c.1857C>A p.D619E | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV100513873; called by muse, mutect2, varscan2
- PCDHGA10 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99538651; called by muse, mutect2, varscan2
- PCDHGB7 | c.1896G>C p.L632F | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.798); catalogued as COSV99538654; called by muse, mutect2, varscan2
- PDZRN3 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55210948, COSV99729665; called by muse, mutect2, varscan2
- PLEC | c.11971C>T p.R3991C (on ENST00000322810 / NM_201380.4; = p.R3881C on NM_000445.5) | Missense Mutation (SNP) | VAF 34/1026 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs782359004; called by muse, mutect2
- POLQ | c.5993C>T p.P1998L | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99952288; called by muse, mutect2, varscan2
- POR | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as rs1347157369, COSV101203634; called by muse, mutect2
- PRPF8 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517509; called by muse, mutect2, varscan2
- PSD2 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs200345805; called by mutect2, varscan2
- RIMKLA | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV101290564; called by muse, mutect2, varscan2
- RNF112 | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101465414; called by muse, mutect2, varscan2
- RXFP1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100313777; called by muse, mutect2, varscan2
- SCN5A | c.1912G>A p.G638S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV100348510; called by muse, mutect2, varscan2
- SLC34A1 | c.1728G>A p.W576* | Nonsense Mutation (SNP) | VAF 143/469 reads (30%) | catalogued as COSV99499708; called by muse, mutect2, varscan2
- SLC39A11 | c.563G>A p.G188D (on ENST00000542342 / NM_001159770.2; = p.G181D on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.094); catalogued as rs373163649, COSV99723120; called by muse, mutect2, varscan2
- TCN1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs145109452; called by muse, mutect2, varscan2
- TECPR2 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1457303148, COSV100850000; called by muse, mutect2
- TEKT3 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100107075; called by muse, mutect2, varscan2
- TLL1 | c.2735C>A p.P912Q | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99287405; called by muse, mutect2, varscan2
- TMEM116 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374733446; called by muse, mutect2, varscan2
- TNPO1 | c.1141T>A p.W381R | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100473447; called by muse, mutect2, varscan2
- TRDMT1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs780057128, COSV100003946; called by muse, mutect2, varscan2
- TUB | c.752T>G p.L251R (on ENST00000299506 / NM_177972.3; = p.L306R on NM_003320.4) | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100210220, COSV55107233; called by muse, mutect2
- TUBB8 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV100226060; called by muse, mutect2, varscan2
- VSIR | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs758679492, COSV99821077, COSV99824129; called by muse, mutect2, varscan2
- WDFY3 | c.8279C>T p.T2760I | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99883629; called by muse, mutect2, varscan2
- WNT9A | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99688254; called by muse, mutect2, varscan2
- ZNF57 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100182911; called by muse, mutect2, varscan2
- ZNF772 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV100582835; called by muse, mutect2, varscan2
- EHBP1L1 | c.1935del p.T646Qfs*25 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, pindel, varscan2
- HRG | c.236dup p.V80Gfs*9 | Frame Shift Ins (INS) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- MRPL22 | c.63del p.K22Sfs*53 | Frame Shift Del (DEL) | VAF 39/163 reads (24%) | called by mutect2, pindel, varscan2
- PLPP2 | c.219del p.A74Pfs*35 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- TAT | c.837dup p.K280Qfs*17 | Frame Shift Ins (INS) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- AP2A2 | c.2085C>T p.V695= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs376836623; called by muse, mutect2, varscan2
- CD79A | c.438A>G p.T146= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99702004; called by muse, mutect2, varscan2
- CEACAM7 | c.18C>A p.A6= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99137232; called by muse, mutect2, varscan2
- COL11A1 | c.3672A>T p.P1224= | Silent (SNP) | VAF 90/1063 reads (8%) | catalogued as COSV100616612; called by muse, mutect2
- DIS3 | c.1356G>T p.L452= | Silent (SNP) | VAF 164/465 reads (35%) | catalogued as COSV100899890; called by muse, mutect2, varscan2
- EIF2AK3 | c.3264C>T p.L1088= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV57546226; called by muse, mutect2, varscan2
- FAM98B | c.846T>A p.I282= | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as COSV101131566; called by muse, mutect2, varscan2
- FARSA | c.786C>A p.L262= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100108839; called by muse, mutect2, varscan2
- FBXO43 | c.1708C>A p.R570= | Silent (SNP) | VAF 40/363 reads (11%) | catalogued as COSV101413852, COSV71054139, COSV71055382; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2151G>T p.G717= | Silent (SNP) | VAF 95/279 reads (34%) | catalogued as COSV100736422; called by muse, mutect2, varscan2
- INSM2 | c.1614A>G p.P538= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99354843; called by muse, mutect2, varscan2
- KCNB2 | c.624T>C p.I208= | Silent (SNP) | VAF 157/422 reads (37%) | catalogued as COSV101578791; called by muse, varscan2
- KCNMB3 | c.804T>C p.I268= | Silent (SNP) | VAF 42/230 reads (18%) | catalogued as COSV99837820; called by muse, mutect2, varscan2
- LILRA4 | c.1392A>G p.L464= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs770028972, COSV99393117; called by muse, mutect2, varscan2
- MAN2A1 | c.1713T>A p.A571= | Silent (SNP) | VAF 161/762 reads (21%) | catalogued as COSV54849600, COSV99811102; called by muse, varscan2
- PRKX | c.535C>T p.L179= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV99468098; called by muse, mutect2, varscan2
- SEC14L5 | c.1038G>A p.G346= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99228912; called by muse, mutect2, varscan2
- SENP5 | c.1266G>T p.V422= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100052005; called by muse, mutect2, varscan2
- SHANK3 | c.549G>A p.G183= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs1426256966, COSV99436998; called by muse, mutect2, varscan2
- SLC30A8 | c.192G>A p.A64= | Silent (SNP) | VAF 93/466 reads (20%) | catalogued as COSV69971919, COSV69973680; called by muse, mutect2, varscan2
- SNAPC1 | c.837A>G p.S279= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV99359258; called by muse, mutect2, varscan2
- TBC1D22B | c.1158G>T p.R386= | Silent (SNP) | VAF 34/181 reads (19%) | catalogued as COSV100996819, COSV100996908; called by muse, mutect2, varscan2
- TEX14 | c.4056G>A p.T1352= (on ENST00000240361 / NM_001201457.2; = p.T1306= on NM_031272.5) | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs372034132, COSV99542892; called by muse, mutect2
